Somatic mutation profile of tumor specimen MP2PRT-PARWYI-TMP1-A (aliquot MP2PRT-PARWYI-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARWYI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,721 days).
Specimen MP2PRT-PARWYI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad19ab39-0657-4506-b86f-e522ed4c9c99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWYI-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWYI-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eb9629a-4a55-4ce3-8d97-53628897bc08

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 61/277 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KSR2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271054017, COSV56683714; called by muse, mutect2, varscan2
- SCN11A | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763315846, COSV56578796; ClinVar: uncertain significance; called by muse, mutect2
- SLC41A2 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 20/455 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as COSV51610776; called by muse, mutect2
- SOGA3 | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 37/659 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV64108739; called by muse, mutect2
- STAG2 | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.371); catalogued as rs866361916, COSV54357629; called by muse, mutect2
- TAF1 | c.715C>T p.R239W (on ENST00000373790 / NM_138923.4; = p.R260W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs751942774; called by muse, mutect2
- TRRAP | c.10618C>T p.R3540W (on ENST00000359863 / NM_001244580.1; = p.R3511W on NM_003496.3) | Missense Mutation (SNP) | VAF 19/438 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62847305; called by muse, mutect2
- ARID5B | c.2137_2138dup p.P714Hfs*4 | Frame Shift Ins (INS) | VAF 127/430 reads (30%) | called by mutect2, pindel, varscan2
- FAM83H | c.2687G>C p.G896A | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SLC5A4 | c.1158G>T p.M386I | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.291); called by muse, mutect2
- USP32 | c.4623C>A p.Y1541* | Nonsense Mutation (SNP) | VAF 82/248 reads (33%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3993G>A p.S1331= | Silent (SNP) | VAF 212/581 reads (36%) | catalogued as rs371623145, COSV60099429; called by muse, mutect2, varscan2
- CDH22 | c.1188G>A p.P396= | Silent (SNP) | VAF 38/710 reads (5%) | catalogued as rs771584992, COSV64838280; called by muse, mutect2
- PTPRT | c.3189G>T p.L1063= | Silent (SNP) | VAF 114/506 reads (23%) | called by muse, mutect2
- TEKT3 | c.651A>G p.A217= | Silent (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- TRAM1L1 | c.903G>C p.L301= | Silent (SNP) | VAF 80/345 reads (23%) | called by muse, mutect2, varscan2
- ZNF532 | c.1044G>A p.P348= | Silent (SNP) | VAF 36/488 reads (7%) | catalogued as rs777310864, COSV60172606; called by muse, mutect2
- LIAS | c.299+1718G>A | Intron (SNP) | VAF 64/243 reads (26%) | catalogued as rs143321910; called by muse, mutect2, varscan2
